Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A41B, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A41B-01A (Primary Tumor).

Procurement Date: L Laterality:Nodular melanoma (pigmented) with ulceration, formed of spindle cells, with lymphoid infiltration. Breslow's depth is 2.8 cm. Clark's level V.

Path Report:SKIN TISSUE CHECKLIST

Specimen type: Excision of skin lesion

Tumor site: Skin, shoulder

Tumor size: 2.8 x 0 x 3 cm

Tumor features: Ulcerated, Pigmented

Satellite nodules: Not specified

Histologic type: Nodular melanoma

Histologic grade: Poorly differentiated

Lymph nodes: Not specified

Lymphatic invasion: Present

Venous invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: Breslow's depth is 2.8 cm. Clark's level V.

ICD-O-3

melanoma, nodular

8721/3

Site: Skin, shoulder

C44.6

7-2012
R0

Source: NCI Genomic Data Commons file 93b55f98-ea45-4c84-a95e-d3540e500ec1 (TCGA-EB-A41B.D40D44B2-6D36-45BF-9203-C7A9BD420DE6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).